Somatic mutation profile of tumor specimen ALCH-ACXR-TTP1-A (aliquot ALCH-ACXR-TTP1-A-1-0-D-A502-36) from ALCHEMIST case ALCH-ACXR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.1 years (29,639 days).
Specimen ALCH-ACXR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 579de9c9-5922-40c8-8298-4010971e8cb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ACXR-NB1-A (Blood Derived Normal), aliquot ALCH-ACXR-NB1-A-1-0-D-A502-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81384d41-e7e5-43f1-9233-536f420d6ff2

The open-access MAF lists 134 somatic variants for this specimen: 85 protein-altering or splice-affecting, 37 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 37, Nonsense Mutation 5, Intron 5, 5'UTR 2, 3'Flank 2, RNA 2, 5'Flank 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 327/1263 reads (26%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.532C>G p.H178D | Missense Mutation (SNP) | VAF 186/734 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795203, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 206/950 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.557); catalogued as COSV56848125; called by muse, varscan2
- ANKRD35 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 30/592 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV100841869; called by muse, mutect2
- ARHGAP6 | c.2822G>A p.R941H (on ENST00000337414 / NM_013427.3; = p.R738H on NM_013423.3) | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1417080203; called by muse, mutect2
- ATP11C | c.3105C>G p.F1035L | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100558430; called by muse, varscan2
- CDH9 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50252882; called by muse, mutect2
- CDT1 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 42/576 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs1373498979; called by muse, mutect2
- CFAP97D1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 35/506 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs535898355, COSV99871451; called by muse, mutect2
- CSMD1 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 52/730 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.321); catalogued as rs780409660, COSV68263655; called by muse, mutect2
- DNAH10 | c.5233G>A p.A1745T (on ENST00000409039; = p.A1684T on NM_207437.3) | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs1345042500, COSV68996611; called by muse, mutect2
- ERCC2 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 323/973 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs778075234, COSV101228708; called by muse, mutect2, varscan2
- FAM47C | c.576G>C p.E192D | Missense Mutation (SNP) | VAF 25/430 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV63725191; called by muse, mutect2
- FAT3 | c.12694G>A p.V4232M | Missense Mutation (SNP) | VAF 48/756 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53078476, COSV53080671; called by muse, mutect2
- GRIA1 | c.1451G>C p.G484A | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV99598150; called by muse, mutect2
- GRM8 | c.401C>G p.A134G | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV58854381; called by muse, mutect2
- H2BC13 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 91/835 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.246); catalogued as COSV100704343, COSV62440776; called by muse, mutect2, varscan2
- HMBS | c.753G>T p.R251S | Missense Mutation (SNP) | VAF 76/568 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV53828453; called by muse, mutect2, varscan2
- ITGA8 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.913); catalogued as COSV100959558, COSV65223898; called by muse, mutect2
- LRP6 | c.1802A>G p.H601R | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53784664; called by muse, mutect2, varscan2
- MARK2 | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.07); catalogued as COSV104407947; called by muse, mutect2
- NAV3 | c.3364G>A p.D1122N | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99897541; called by muse, mutect2
- OR4A15 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100124198; called by muse, mutect2, varscan2
- PPFIA4 | c.1241G>A p.R414H (on ENST00000447715; = p.R410H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/506 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs937938045, COSV99690477; called by muse, mutect2
- PRKD2 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 27/405 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52184589; called by muse, mutect2
- PTCHD4 | c.1590G>A p.W530* | Nonsense Mutation (SNP) | VAF 14/139 reads (10%) | catalogued as COSV100261219; called by muse, mutect2
- RBM33 | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 38/562 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs985826385; called by muse, mutect2
- ROBO4 | c.2626G>A p.G876S | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100127525; called by muse, mutect2, varscan2
- RPA1 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 50/527 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as COSV54609165, COSV54613342; called by muse, mutect2
- RRP8 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 16/272 reads (6%) | catalogued as rs1201939025, COSV99601778; called by muse, mutect2
- SLFN14 | c.1711C>T p.L571F | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1299328471; called by muse, mutect2
- TMEM185B | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs781680405; called by muse, mutect2, varscan2
- TMEM8B | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 35/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65076328; called by muse, mutect2
- TRIM15 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 129/502 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs1308727094; called by muse, mutect2, varscan2
- TTN | c.69616G>T p.E23206* (on ENST00000591111; = p.E15782* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 41/201 reads (20%) | catalogued as COSV60150533; called by muse, mutect2, varscan2
- VLDLR | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 53/483 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as rs759853335, COSV66074467; called by muse, mutect2, varscan2
- WDR1 | c.960T>G p.S320R (on ENST00000382452; = p.S180R on NM_005112.5) | Missense Mutation (SNP) | VAF 51/643 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs1472084244; called by muse, mutect2
- ZMAT1 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV65658935; called by muse, mutect2, varscan2
- ZNF324 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 25/460 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1217260084; called by muse, mutect2
- ZNF469 | c.8267G>A p.R2756Q (on ENST00000437464; = p.R2784Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 64/894 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.102); catalogued as rs1047653960; called by muse, mutect2
- ZNF541 | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 64/894 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1274817554, COSV54545343; called by muse, mutect2
- ADGRB3 | c.1640G>A p.R547K | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRG4 | c.3177G>A p.M1059I | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP6V0A1 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.134); called by muse, mutect2
- ATP9B | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 36/427 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- CACNA1C | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.995); called by muse, mutect2
- CCDC167 | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 98/700 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); called by muse, varscan2
- CDH10 | c.1492T>C p.C498R | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDHR4 | c.978G>C p.M326I | Missense Mutation (SNP) | VAF 81/459 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPLANE1 | c.9436G>C p.E3146Q | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.404); called by muse, mutect2
- CYP2F1 | c.729C>A p.D243E | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- DHX30 | c.1897del p.H633Tfs*23 (on ENST00000445061 / NM_138615.3; = p.H594Tfs*23 on NM_014966.3) | Frame Shift Del (DEL) | VAF 24/210 reads (11%) | called by mutect2, pindel, varscan2
- DMBT1 | c.5098A>C p.I1700L (on ENST00000338354 / NM_001377530.1; = p.I943L on NM_004406.3) | Missense Mutation (SNP) | VAF 290/1861 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DNAH5 | c.9883G>A p.E3295K | Missense Mutation (SNP) | VAF 57/842 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2
- DNALI1 | c.131A>T p.E44V (on ENST00000296218; = p.E22V on NM_003462.5) | Missense Mutation (SNP) | VAF 31/467 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); called by muse, mutect2
- ELP3 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT2 | c.3190G>C p.D1064H | Missense Mutation (SNP) | VAF 33/409 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HNRNPUL2 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 31/424 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.042); called by muse, mutect2
- IGSF3 | c.3483G>C p.K1161N (on ENST00000369486 / NM_001007237.3; = p.K1181N on NM_001542.4) | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IP6K3 | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 67/545 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- KIF16B | c.3766G>A p.V1256M | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.253); called by muse, mutect2
- MAF | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 43/728 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2
- MYO18B | c.6736C>T p.P2246S | Missense Mutation (SNP) | VAF 66/420 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NLK | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- NLRP2 | c.1842G>C p.E614D | Missense Mutation (SNP) | VAF 76/1406 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.294); called by muse, mutect2
- NOX3 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRTN | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); called by muse, mutect2
- PCDHA4 | c.1898C>T p.T633I | Missense Mutation (SNP) | VAF 50/664 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.25); called by muse, mutect2
- PCDHB16 | c.1406A>T p.H469L | Missense Mutation (SNP) | VAF 210/1833 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCK2 | c.1355G>T p.G452V | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDILT | c.1411C>G p.Q471E | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PDXDC1 | c.1861C>G p.Q621E | Missense Mutation (SNP) | VAF 114/1379 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.012); called by muse, mutect2
- PKD2L2 | c.780A>G p.I260M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PP2D1 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- PRPF6 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 96/1291 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2
- RAG2 | c.1337G>A p.C446Y | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RNF31 | c.2264A>G p.D755G | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2
- RYR2 | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 132/354 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SPAG4 | c.186G>C p.L62F | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ST6GALNAC6 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 44/806 reads (5%) | called by muse, mutect2
- SYNGR4 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TAOK1 | c.741_742dup p.N248Ifs*12 | Frame Shift Ins (INS) | VAF 6/70 reads (9%) | called by mutect2, pindel
- TSHZ3 | c.2518C>A p.R840S | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- ZMPSTE24 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ZNF644 | c.1557A>C p.E519D | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CDH6 | c.786C>T p.N262= | Silent (SNP) | VAF 42/401 reads (10%) | catalogued as rs753390985, COSV54064859; called by muse, mutect2, varscan2
- CDHR3 | c.1887G>T p.L629= | Silent (SNP) | VAF 79/527 reads (15%) | called by muse, mutect2, varscan2
- CLCN1 | c.1146C>T p.L382= | Silent (SNP) | VAF 27/496 reads (5%) | called by muse, mutect2
- COL18A1 | c.2835C>T p.P945= (on ENST00000359759 / NM_130444.3; = p.P710= on NM_030582.4) | Silent (SNP) | VAF 39/456 reads (9%) | called by muse, mutect2
- CPT1A | c.376C>T p.L126= | Silent (SNP) | VAF 58/902 reads (6%) | called by muse, mutect2
- DAAM1 | c.678C>A p.I226= | Silent (SNP) | VAF 13/282 reads (5%) | called by muse, mutect2
- DDX19B | c.262C>T p.L88= | Silent (SNP) | VAF 37/516 reads (7%) | called by muse, mutect2
- DGKA | c.1752G>T p.G584= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- EPS8L1 | c.750G>T p.A250= (on ENST00000201647 / NM_133180.3; = p.A123= on NM_017729.3) | Silent (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2
- FBLN5 | c.354G>A p.Q118= | Silent (SNP) | VAF 58/861 reads (7%) | catalogued as COSV99969934; called by muse, mutect2
- FREM2 | c.5460C>G p.G1820= | Silent (SNP) | VAF 37/288 reads (13%) | called by muse, mutect2, varscan2
- GLIS2 | c.852G>A p.T284= | Silent (SNP) | VAF 76/1368 reads (6%) | catalogued as rs779830549; called by muse, mutect2
- LACC1 | c.504G>A p.L168= | Silent (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- LRCOL1 | c.186C>G p.L62= | Silent (SNP) | VAF 42/496 reads (8%) | catalogued as COSV64913116; called by muse, mutect2
- MAGEB6B | c.555G>A p.A185= | Silent (SNP) | VAF 52/354 reads (15%) | catalogued as rs758374357; called by muse, mutect2, varscan2
- MAP3K7 | c.639C>T p.F213= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as rs1375968230; called by muse, mutect2, varscan2
- NDUFV1 | c.1185G>A p.V395= | Silent (SNP) | VAF 87/635 reads (14%) | called by muse, mutect2, varscan2
- NOX1 | c.537G>A p.V179= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- NRG2 | c.237G>A p.R79= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, varscan2
- NUP210L | c.1359C>T p.I453= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs755899462; called by muse, mutect2, varscan2
- NXF3 | c.1302C>T p.L434= | Silent (SNP) | VAF 30/564 reads (5%) | called by muse, mutect2
- OCRL | c.2676G>C p.L892= | Silent (SNP) | VAF 77/634 reads (12%) | called by muse, mutect2, varscan2
- OR14C36 | c.786G>C p.A262= | Silent (SNP) | VAF 33/534 reads (6%) | catalogued as COSV58601678; called by muse, mutect2
- OR8H3 | c.522T>A p.I174= | Silent (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- PPP3R1 | c.276G>A p.L92= | Silent (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2, varscan2
- RAD17 | c.1803G>A p.L601= (on ENST00000380774 / NM_133339.2; = p.L590= on NM_002873.1) | Silent (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
- REEP2 | c.411C>T p.A137= | Silent (SNP) | VAF 44/264 reads (17%) | catalogued as rs767756939; called by muse, mutect2, varscan2
- SATB2 | c.66C>T p.D22= | Silent (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- SCN4B | c.153G>T p.L51= | Silent (SNP) | VAF 24/382 reads (6%) | called by muse, mutect2
- SLC15A1 | c.1251A>C p.T417= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- SLC17A7 | c.663G>C p.A221= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as rs1196389313, COSV99677075; called by muse, mutect2
- SOBP | c.1236C>A p.I412= | Silent (SNP) | VAF 8/38 reads (21%) | called by mutect2, varscan2
- SPHKAP | c.2148G>C p.V716= | Silent (SNP) | VAF 24/211 reads (11%) | catalogued as COSV60873891; called by muse, mutect2, varscan2
- SPTAN1 | c.6238C>T p.L2080= | Silent (SNP) | VAF 22/403 reads (5%) | called by muse, mutect2
- TCF25 | c.396G>A p.Q132= | Silent (SNP) | VAF 33/472 reads (7%) | called by muse, mutect2
- TGFBI | c.573C>T p.L191= | Silent (SNP) | VAF 34/650 reads (5%) | called by muse, mutect2
- UNC13D | c.2742G>A p.V914= | Silent (SNP) | VAF 57/553 reads (10%) | catalogued as rs777262533, COSV52885328; called by muse, mutect2, varscan2
- ABCC6P1 | n.1153C>T | RNA (SNP) | VAF 50/1074 reads (5%) | called by muse, mutect2
- AL353804.7 | chrX:73851141 G>A | 3'Flank (SNP) | VAF 50/883 reads (6%) | called by muse, mutect2
- BMERB1 | c.230+17568T>C | Intron (SNP) | VAF 26/536 reads (5%) | called by muse, mutect2
- DMTN | c.295-37del | Intron (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel
- KNOP1P1 | n.540T>C | RNA (SNP) | VAF 42/468 reads (9%) | called by muse, mutect2
- MS4A6A | c.283-485A>G | Intron (SNP) | VAF 9/79 reads (11%) | catalogued as rs1046036496; called by muse, mutect2, varscan2
- RMDN1 | chr8:86470252 C>G | 3'Flank (SNP) | VAF 20/512 reads (4%) | called by muse, mutect2
- SCUBE1 | c.727+2671C>A | Intron (SNP) | VAF 68/822 reads (8%) | called by muse, mutect2
- SPTAN1 | c.5978-10C>T | Intron (SNP) | VAF 80/1234 reads (6%) | catalogued as rs773841663; called by muse, mutect2
- SUCO | chr1:172532779 C>G | 5'Flank (SNP) | VAF 183/486 reads (38%) | called by muse, mutect2, varscan2
- TCF21 | c.-37C>A | 5'UTR (SNP) | VAF 118/943 reads (13%) | called by mutect2, varscan2
- YARS1 | c.-5G>A | 5'UTR (SNP) | VAF 51/641 reads (8%) | called by muse, mutect2
